CCDI case PBCADX — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Gliomas; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/73070b59-cbd6-4e2d-a0c7-175c47b4c91f

Demographics
Sex at birth: male; Ethnicity: hispanic or latino; Vital status: Alive.

Diagnoses (1)
1. Glioma, malignant: ICD-O-3 morphology code: 9380/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 17.0 years (6,204 days).

Biospecimens (3 samples)
- Sample 0DRY7M: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DRY80: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DRY82: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
